Somatic mutation profile of tumor specimen TCGA-EB-A44N-01A (aliquot TCGA-EB-A44N-01A-11D-A25O-08) from TCGA case TCGA-EB-A44N, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 59.2 years (21,623 days).
Specimen TCGA-EB-A44N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a857111-2858-4bb3-a72d-3f1757289909.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A44N-10A (Blood Derived Normal), aliquot TCGA-EB-A44N-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62f83795-7d29-4ea0-b25d-bf396bdd1a6f

The open-access MAF lists 183 somatic variants for this specimen: 116 protein-altering or splice-affecting, 64 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 64, Nonsense Mutation 14, Frame Shift Del 4, Splice Site 2, Intron 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 3/26 reads (12%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2
- MUTYH | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769237459, CM053996, COSV58343540; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs387906854, CM116904, COSV59280826; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.6394C>T p.Q2132* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as rs1057516489, COSV62133968; ClinVar: likely pathogenic; called by muse, mutect2
- A1CF | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV50957573; called by muse, varscan2
- ADAM18 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV55844140; called by muse, mutect2
- ANAPC1 | c.3680T>A p.L1227H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61974323; called by mutect2, varscan2
- ANKRD13C | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52029216; called by muse, mutect2, varscan2
- APBA1 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55222124; called by muse, mutect2, varscan2
- ASB5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV56668815, COSV56670712; called by muse, mutect2, varscan2
- ASIC5 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs866211558, COSV73332586; called by muse, mutect2, varscan2
- ASTN1 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.858); catalogued as COSV56062084; called by muse, mutect2
- BRSK1 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58664798; called by muse, mutect2
- C7 | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349938004, COSV57471155; called by muse, mutect2
- CACNA1E | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62383253; called by muse, mutect2, varscan2
- CAMKK1 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50114087; called by muse, mutect2, varscan2
- CAMSAP1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1429446066, COSV56718701; called by muse, mutect2, varscan2
- CCDC7 | c.3970C>T p.P1324S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV56537176; called by muse, mutect2, varscan2
- CDH12 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765231841, COSV66389349; called by muse, mutect2, varscan2
- CEACAM7 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.668); catalogued as COSV99137150; called by muse, mutect2, varscan2
- CFAP53 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs550993731, COSV68351359; called by muse, mutect2, varscan2
- CHIT1 | c.1279C>T p.L427F | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV55145401; called by muse, mutect2, varscan2
- COL12A1 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.326); catalogued as COSV59390021; called by muse, mutect2, varscan2
- COL15A1 | c.2879C>T p.P960L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs866201689, COSV66641493; called by muse, mutect2, varscan2
- COL21A1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55154381; called by muse, mutect2, varscan2
- CUBN | c.3745C>T p.R1249C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs368224687; called by muse, mutect2, varscan2
- DCUN1D3 | c.222T>G p.D74E | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV60952486; called by muse, mutect2
- DSCAM | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs766975740, COSV68021375; called by muse, mutect2
- EIPR1 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs1481271833, COSV66128127; called by muse, mutect2, varscan2
- EPHA7 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs749418654, COSV65168614; called by muse, mutect2, varscan2
- EPHA8 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV51262791; called by muse, mutect2, varscan2
- F11R | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs867883705, COSV57036110; called by muse, mutect2, varscan2
- FAM234B | c.1760T>A p.M587K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.32); catalogued as COSV52192712; called by muse, mutect2, varscan2
- FAM47C | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV63723927; called by muse, mutect2, varscan2
- FARP2 | c.2509C>T p.R837W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs143557762; called by muse, mutect2, varscan2
- FBXO39 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV58621074; called by muse, mutect2, varscan2
- FLT3 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751562024, COSV54045211; called by muse, mutect2, varscan2
- FMO4 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63000640; called by muse, mutect2, varscan2
- GABRA6 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs769441572, COSV50877773, COSV99194188; called by muse, mutect2, varscan2
- GIMAP8 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as rs761170315, COSV56229886; called by muse, mutect2, varscan2
- GYG2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767864277, COSV58549244, COSV58549761; called by muse, mutect2, varscan2
- HDAC3 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV59495178; called by muse, mutect2, varscan2
- HSPBAP1 | c.1163T>C p.F388S | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60241337; called by muse, mutect2
- ITGAE | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV53989611; called by muse, mutect2, varscan2
- KIF6 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs866995579, COSV54667903; called by muse, mutect2, varscan2
- KIR3DL1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769992136, COSV58488182; called by muse, mutect2, varscan2
- KRTAP13-4 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV61878481; called by muse, mutect2
- LACRT | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV57687749; called by muse, mutect2
- LLGL2 | c.2462T>G p.V821G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51342473; called by muse, mutect2, varscan2
- MED24 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as rs1472128763, COSV62417179; called by muse, mutect2, varscan2
- MELK | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV53197117; called by muse, mutect2, varscan2
- MGAM | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs541807685, COSV71885000; called by muse, mutect2
- MMP17 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765754043, COSV62178469; called by muse, mutect2, varscan2
- MPZL3 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs757878936, COSV54052685; called by muse, mutect2, varscan2
- MROH2B | c.3870G>A p.M1290I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.406); catalogued as COSV68181239; called by muse, mutect2, varscan2
- MROH2B | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68181244; called by muse, mutect2
- MUC16 | c.32425C>T p.R10809* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as rs749875229, COSV67446949, COSV67480671; called by muse, mutect2, varscan2
- N4BP2 | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.068); catalogued as COSV54699350; called by muse, mutect2, varscan2
- NCKAP1 | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV62939885; called by muse, mutect2
- NEUROD1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs752873809, COSV54548222; called by muse, mutect2, varscan2
- NPAP1 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as COSV61504578, COSV61504721; called by muse, mutect2, varscan2
- NT5C1B | c.982G>A p.E328K (on ENST00000359846 / NM_001199086.2; = p.E268K on NM_033253.4) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1233128130, COSV58394486; called by muse, mutect2, varscan2
- NTRK2 | c.1534G>A p.E512K (on ENST00000323115 / NM_001369534.1; = p.E528K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52854881; called by muse, mutect2
- NTRK3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62296448; called by muse, mutect2, varscan2
- OBSCN | c.3455G>A p.R1152K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV52743512; called by muse, mutect2, varscan2
- OR2T4 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs746143008, COSV63543386; called by muse, mutect2, varscan2
- OR4D9 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61434098; called by muse, mutect2
- PATE1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV59824144, COSV99986261; called by muse, mutect2, varscan2
- PCDHGB1 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV53903688; called by muse, mutect2, varscan2
- PDE7B | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs193920799, COSV57492185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLDB2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs780804335, COSV67308399; called by muse, mutect2, varscan2
- PLCXD3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as rs1262014399, COSV60605153, COSV60606590; called by muse, mutect2, varscan2
- PRDM11 | c.1016T>C p.F339S (on ENST00000530656 / NM_001359633.1; = p.F305S on NM_001256695.1) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55437675; called by muse, mutect2, varscan2
- PREX2 | c.3231G>T p.K1077N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as COSV55752338; called by muse, mutect2, varscan2
- RASGRF2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1170812859, COSV54122195; called by muse, mutect2, varscan2
- RLF | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV65650732; called by muse, mutect2, varscan2
- ROR1 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64284149; called by muse, mutect2, varscan2
- RTL3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs754780962, COSV100329782, COSV58183264; called by muse, mutect2
- SAXO2 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as COSV59753398; called by muse, mutect2, varscan2
- SDK2 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66181753; called by muse, mutect2, varscan2
- SELE | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV60974069; called by muse, mutect2, varscan2
- SLC14A2 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV54906519; called by muse, mutect2
- SLC20A1 | c.964G>T p.G322* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV55610285; called by muse, mutect2
- SLC22A14 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV56196700; called by muse, mutect2, varscan2
- SLC27A2 | c.893G>A p.W298* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as rs1486235469, COSV51057574; called by muse, mutect2
- SLC29A3 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64384543; called by muse, mutect2, varscan2
- SLC6A11 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV54390102; called by muse, mutect2, varscan2
- STPG2 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as rs375848968, COSV54808861; called by muse, mutect2, varscan2
- STXBP5L | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV56501262; called by muse, mutect2
- SUZ12 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV59498175, COSV59502391; called by muse, mutect2, varscan2
- TARS2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV64694581; called by muse, mutect2, varscan2
- THSD7B | c.3866C>A p.P1289H (on ENST00000272643; = p.P1287H on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55657345; called by muse, mutect2, varscan2
- TLL1 | c.2737G>A p.G913R | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.898); catalogued as COSV50262523; called by muse, mutect2, varscan2
- TLR10 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs199605976, COSV58299237; called by mutect2, varscan2
- TP73 | c.689T>A p.V230D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as COSV60698707, COSV60698731; called by muse, mutect2
- TRMT6 | c.129-1G>A p.X43_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52542728; called by muse, mutect2
- TROAP | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV57743195; called by muse, mutect2, varscan2
- TTF2 | c.2521C>T p.Q841* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV65632079; called by muse, mutect2, varscan2
- USP29 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV54140154; called by muse, mutect2, varscan2
- USP9Y | c.1383T>A p.F461L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59098718; called by muse, mutect2, varscan2
- VASH1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51335283; called by muse, mutect2, varscan2
- VDR | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as rs980041568, CM931248, COSV57466981; called by muse, mutect2, varscan2
- WSB1 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52214619; called by muse, mutect2, varscan2
- ZNF257 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV71306236; called by muse, mutect2, varscan2
- ZNF439 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as rs373484496; called by muse, mutect2, varscan2
- ZNF790 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); catalogued as COSV63211995, COSV63213591; called by muse, mutect2, varscan2
- ZNF98 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV63334650; called by muse, mutect2
- ADCY9 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- CTNND2 | c.2743del p.A915Rfs*23 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel*
- IGHV3-73 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A14 | c.201del p.Y67* | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- PPM1D | c.1370_1372delinsTT p.A457Vfs*8 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2*
- SOCS7 | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TIE1 | c.2344del p.T782Pfs*35 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- ZNF84 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2
- ABCC4 | c.2121T>G p.A707= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV65309926; called by muse, mutect2, varscan2
- ADCY1 | c.2589C>T p.S863= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV52030552; called by muse, mutect2
- ADGRE1 | c.2511G>A p.G837= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99165076; called by muse, mutect2, varscan2
- ANK1 | c.5064C>T p.T1688= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs766159273, COSV55873686; called by muse, mutect2, varscan2
- ASS1 | c.891C>T p.I297= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs200900381, COSV61688516; called by muse, mutect2, varscan2
- CACNA1A | c.2523G>A p.K841= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV64190416; called by muse, mutect2
- CCDC173 | c.1449G>A p.S483= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs774927146, COSV53641389; called by muse, mutect2, varscan2
- CCDC88C | c.696C>T p.S232= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV66234407; called by muse, mutect2, varscan2
- CCR5 | c.780C>T p.F260= | Silent (SNP) | VAF 31/229 reads (14%) | catalogued as COSV52750899; called by muse, mutect2, varscan2
- CEACAM7 | c.561G>A p.L187= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99137151; called by muse, mutect2, varscan2
- CFH | c.1347C>T p.S449= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs963283450, COSV66405974; called by muse, varscan2
- CHST4 | c.294A>T p.I98= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58296527; called by muse, mutect2, varscan2
- CWH43 | c.1398G>A p.E466= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1451811700, COSV99892933; called by muse, mutect2
- CXorf38 | c.415T>C p.L139= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV59947268; called by muse, mutect2, varscan2
- DENND2A | c.2121C>T p.F707= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV52048013; called by muse, mutect2
- DGKI | c.699A>G p.K233= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55937566; called by muse, mutect2, varscan2
- DNAH5 | c.7950G>A p.K2650= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV54205435; called by muse, mutect2, varscan2
- DOP1B | c.2466C>T p.N822= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV67692217; called by muse, mutect2, varscan2
- EMC10 | c.675A>G p.K225= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100618416; called by mutect2, varscan2
- EPHA10 | c.1659G>A p.G553= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV57621541; called by muse, mutect2, varscan2
- EVC | c.633G>A p.L211= | Silent (SNP) | VAF 39/276 reads (14%) | catalogued as rs778879455, COSV53829471; called by muse, mutect2, varscan2
- EXPH5 | c.2316C>T p.V772= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV56199121; called by muse, mutect2, varscan2
- FLNB | c.1210T>C p.L404= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV55871248; called by muse, mutect2, varscan2
- FZD10 | c.1149C>T p.V383= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1296719103, COSV57472242; called by muse, mutect2, varscan2
- GABBR2 | c.1374C>T p.F458= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52294075; called by muse, mutect2, varscan2
- GIMAP8 | c.585G>A p.T195= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs1451219728, COSV56229896; called by muse, mutect2, varscan2
- GJA5 | c.381G>C p.V127= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV54783033; called by muse, mutect2, varscan2
- IGKV6D-21 | c.231C>T p.V77= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs760149993; called by muse, mutect2, varscan2
- IRS1 | c.535C>T p.L179= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV59333650; called by muse, mutect2
- ITGB4 | c.1065C>T p.I355= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs1568348764, COSV52322099; called by muse, mutect2, varscan2
- KMT2C | c.3042G>A p.G1014= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV51310624; called by muse, mutect2, varscan2
- LARGE2 | c.1662G>A p.P554= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs779748018, COSV57649897; called by mutect2, varscan2
- LRRC20 | c.396C>T p.I132= (on ENST00000355790 / NM_207119.3; = p.I82= on NM_018239.4) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs187434356, COSV62937262; called by muse, mutect2, varscan2
- LTN1 | c.3579A>T p.I1193= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV63733045; called by muse, mutect2, varscan2
- MAPK7 | c.1038C>T p.F346= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV55189434; called by muse, mutect2
- MMP11 | c.465C>T p.I155= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV53155451; called by muse, mutect2, varscan2
- MYH2 | c.4578G>A p.G1526= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs267604718, COSV55432125; called by mutect2, varscan2
- MYH8 | c.4260G>A p.T1420= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs569728381, COSV67960211; called by muse, mutect2, varscan2
- NDRG4 | c.339G>A p.V113= (on ENST00000570248 / NM_001378344.1; = p.V145= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1490018204, COSV50746573; called by muse, mutect2
- NLE1 | c.90T>C p.G30= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV62603725; called by muse, mutect2, varscan2
- OR2M3 | c.810G>A p.Q270= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV71758875; called by muse, mutect2, varscan2
- OR2M7 | c.141C>T p.L47= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as COSV58738061; called by muse, mutect2, varscan2
- PFKFB4 | c.684C>T p.N228= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV51679764; called by muse, mutect2, varscan2
- PKLR | c.228G>T p.L76= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV61360487; called by muse, mutect2, varscan2
- PLCL1 | c.699G>A p.E233= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV70821552; called by muse, mutect2, varscan2
- PLCXD3 | c.519G>A p.A173= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2, varscan2
- PLXNA2 | c.2823C>T p.F941= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV65437861; called by muse, mutect2, varscan2
- QPCT | c.84G>A p.G28= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs746307074, COSV58119077; called by muse, mutect2, varscan2
- REPS2 | c.1803C>T p.V601= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV58179154; called by muse, mutect2, varscan2
- RIMBP2 | c.798C>T p.D266= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV55465593, COSV99900436; called by muse, mutect2, varscan2
- RNF111 | c.2088A>T p.I696= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV62083830; called by muse, mutect2, varscan2
- RP1L1 | c.7114C>T p.L2372= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV66751990; called by muse, mutect2, varscan2
- RUFY4 | c.1110C>T p.I370= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- SCFD1 | c.381G>A p.L127= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100356124; called by muse, mutect2, varscan2
- SCN10A | c.2604C>T p.I868= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV71860354; called by muse, mutect2, varscan2
- SLC14A2 | c.321C>T p.I107= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV54906509; called by muse, mutect2
- SLFNL1 | c.105G>A p.T35= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs551996213, COSV57234134; called by muse, mutect2
- TRRAP | c.4567C>T p.L1523= (on ENST00000359863 / NM_001244580.1; = p.L1505= on NM_003496.3) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV62839452; called by muse, mutect2, varscan2
- TSSK1B | c.429C>T p.L143= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV66814878; called by muse, mutect2, varscan2
- TTN | c.28704A>G p.E9568= (on ENST00000591111; = p.E8641= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100598008; called by muse, mutect2, varscan2
- USH2A | c.9684G>A p.Q3228= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs200038117, COSV56331259; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZC3HC1 | c.1470C>T p.F490= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV61297343; called by muse, mutect2, varscan2
- ZNF418 | c.1407C>T p.L469= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV68675579; called by muse, mutect2, varscan2
- ZSWIM5 | c.1437C>T p.S479= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV62732658; called by muse, mutect2, varscan2
- CCHCR1 | c.-51-417C>T | Intron (SNP) | VAF 5/33 reads (15%) | catalogued as rs774974628, COSV100883844, COSV66161077; called by muse, mutect2, varscan2
- SLC22A17 | n.1384C>T | RNA (SNP) | VAF 9/49 reads (18%) | catalogued as rs202086254, COSV52834826; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039827 T>C | 5'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
